Gene-level copy-number profile of tumor specimen 1105258 from CPTAC case C524103, project CPTAC-3 (Other and unspecified urinary organs — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Urethra.
Specimen 1105258: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb6c7522-92bd-4a62-ab86-9dc3dcf7d09c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105274 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,398 have no estimate.
https://portal.gdc.cancer.gov/files/15454f13-373c-498f-a2d0-739a833da0e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 2,139; copy number 2: 21,991; copy number 3: 6,356; copy number 4: 20,716; copy number 5: 4,466; copy number 6: 1,600; copy number 7: 411; copy number 8: 388; copy number 9: 56; copy number 10: 27; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,601,416–248,937,043, 19 genes: AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:38,814–46,870, 1 gene: FAM110C.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:49,096–88,208, 2 genes: BNIP3P41, ZNF595.
- chr4:47,831,330–48,936,880, 20 genes (within-gene range 0–4): AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1.
- chr7:63,621,090–63,636,617, 2 genes: MIR4283-2, AC006015.1.
- chr17:142,789–414,023, 8 genes (within-gene range 0–2): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1.
- chr17:31,303,770–31,321,749, 3 genes (within-gene range 0–2): EVI2B, AC134669.1, EVI2A.
- chr17:31,391,675–31,713,853, 14 genes: RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3, AC007923.2, RNU6-1134P.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–2): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene: AC139100.1.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,928 genes in 81 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:193,256,483–198,772,356, 62 genes, copy number 6 (broad region; genes not listed).
- chr2:204,545,475–223,248,794, 345 genes, copy number 6 (broad region; genes not listed).
- chr3:58,008,400–79,767,998, 229 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:212,610–5,019,458, 145 genes, copy number 5–9 (broad region; genes not listed).
- chr4:29,907,659–35,496,003, 28 genes, copy number 6: AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, MAPRE1P2, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr4:176,213,673–178,406,830, 22 genes, copy number 5–6: ASB5, SPCS3-AS1, SPCS3, AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1, LINC01098, LINC01099, RNU1-45P, AC095041.1, RNA5SP173.
- chr5:321,759–23,014,527, 352 genes, copy number 5 (broad region; genes not listed).
- chr5:42,423,439–43,280,850, 26 genes, copy number 5: GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14.
- chr5:64,404,512–65,723,035, 23 genes, copy number 5 (within-gene range 4–5): AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB.
- chr5:72,687,112–77,166,909, 105 genes, copy number 5–6 (broad region; genes not listed).
- chr6:160,531,482–170,279,887, 142 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–52,022,974, 84 genes, copy number 5–6 (broad region; genes not listed).
- chr8:65,526,738–70,071,693, 77 genes, copy number 5 (broad region; genes not listed).
- chr8:70,573,218–74,896,302, 78 genes, copy number 5 (broad region; genes not listed).
- chr8:78,148,101–80,526,265, 37 genes, copy number 5: AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10.
- chr8:90,592,804–101,372,707, 217 genes, copy number 5–7 (broad region; genes not listed).
- chr8:102,125,432–117,318,701, 156 genes, copy number 5 (broad region; genes not listed).
- chr8:122,414,332–123,541,206, 36 genes, copy number 5: SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32.
- chr8:123,984,138–139,704,109, 182 genes, copy number 5–7 (broad region; genes not listed).
- chr10:42,149,310–43,525,217, 44 genes, copy number 5–7: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2.
- chr11:54,591,480–56,361,511, 92 genes, copy number 5 (broad region; genes not listed).
- chr11:56,597,426–63,048,126, 324 genes, copy number 5 (broad region; genes not listed).
- chr11:124,476,963–124,834,487, 22 genes, copy number 5: OR8B9P, OR8B10P, OR8A3P, AP000916.1, OR8B12, OR8A1, OR8Q1P, PANX3, TBRG1, SIAE, RNA5SP352, SPA17, NRGN, AP000866.5, VSIG2, ESAM, AP000866.2, MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4.
- chr12:17,383,352–23,251,499, 79 genes, copy number 6 (broad region; genes not listed).
- chr14:21,698,954–22,190,713, 49 genes, copy number 6: AC243972.3, TRAV2, AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:32,934,396–54,539,292, 328 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:25,051,477–28,859,007, 157 genes, copy number 5 (broad region; genes not listed).
- chr15:97,960,703–99,498,375, 36 genes, copy number 5: ARRDC4, AC024651.1, LINC02251, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.4.
- chr16:30,471,587–31,569,475, 108 genes, copy number 6 (broad region; genes not listed).
- chr17:3,923,870–6,556,555, 99 genes, copy number 8 (broad region; genes not listed).
- chr17:12,991,612–19,214,045, 247 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr17:19,411,125–19,748,943, 28 genes, copy number 5: RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1.
- chr17:21,197,954–22,424,731, 34 genes, copy number 8: TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3.
- chr17:68,511,780–74,314,884, 82 genes, copy number 6 (broad region; genes not listed).
- chr17:74,466,399–76,121,576, 96 genes, copy number 6 (broad region; genes not listed).
- chr17:76,142,465–83,240,804, 307 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr20:32,355,053–64,327,972, 805 genes, copy number 5 (broad region; genes not listed).
- chr21:13,305,152–17,296,596, 83 genes, copy number 5 (broad region; genes not listed).
- chr22:15,282,557–17,570,078, 95 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:18,029,385–50,801,309, 1,240 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
